Gene-level copy-number profile of tumor specimen TCGA-BA-A6DL-01A from TCGA case TCGA-BA-A6DL, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G2; Age at diagnosis: 59.9 years (21,886 days).
Specimen TCGA-BA-A6DL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4b9bcf04-49fc-45c1-842b-7f8d26c7b8f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A6DL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4eaf9fd2-5757-4d32-9dc0-6b512bf109e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 1,953; copy number 2: 6,149; copy number 3: 23,604; copy number 4: 21,323; copy number 5: 3,092; copy number 6: 3,318; copy number 7: 130; copy number 8: 82; copy number 10: 57; copy number 13: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A6DL-01A-21D-A30D-01): tumor purity 0.33, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–31,645,160, 92 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 280 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:82,319,172–82,320,279, 1 gene, copy number 7: RPL7AP23.
- chr6:61,679,961–62,286,225, 1 gene, copy number 7 (within-gene range 6–7): KHDRBS2.
- chr6:62,460,940–63,779,336, 19 genes, copy number 7: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,798,031, 1 gene, copy number 7: AL354719.1.
- chr9:32,293,558–33,025,130, 21 genes, copy number 7–13 (within-gene range 4–13): RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4.
- chr9:35,161,992–36,304,781, 57 genes, copy number 10 (within-gene range 2–10): UNC13B, AL160274.1, ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE.
- chr14:21,918,188–22,509,406, 82 genes, copy number 8 (broad region; genes not listed).
- chr14:78,170,373–79,868,291, 1 gene, copy number 7 (within-gene range 6–7): NRXN3.
- chr14:78,695,321–88,881,078, 97 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
